CCDI case PBCBMD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/a5e60b1d-09f3-459b-a310-1198ef5fd4ad

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 17.7 years (6,454 days).

Biospecimens (3 samples)
- Sample 0DNGG9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNGGE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNGGP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
